Surgical pathology report (de-identified scan), TCGA case TCGA-QT-A5XJ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of North Carolina, specimen TCGA-QT-A5XJ-01A (Primary Tumor).

[page 1 of 6]
ICD-O-3
Pheochromocytoma, malignant
8200/3
Site @ Adrenal gland NOS
@ 74.9
JW 4/2/13

Diagnosis:

A: Lymph node, celiac, biopsy

- Metastatic paraganglioma/pheochromocytoma, no residual lymph node is identified in this specimen

B: Lymph node, retropancreatic, biopsy

- Metastatic paraganglioma/pheochromocytoma, involving 1 of 1 lymph node, size of metastasis 7 mm, no extranodal extension of tumor identified, but tumor is present in afferent lymphatics

C: Lymph node, paraesophageal, biopsy

- Metastatic paraganglioma/pheochromocytoma, involving 1 of 1 lymph node, size of metastasis 2.2 cm, with extranodal extension of tumor identified

D: Lymph nodes, celiac, biopsy

- Metastatic paraganglioma/pheochromocytoma, involving 3 of 3 lymph nodes, size of largest metastasis measures 2.4 cm, with extranodal extension of tumor identified

E: Lymph node, left periaortic, biopsy

- Metastatic paraganglioma/pheochromocytoma, involving 7 of 9 lymph nodes, size of largest metastasis 1.4 cm, with extranodal extension of tumor identified, with perineural space invasion

F: Retroperitoneal tumor with en bloc resection of left kidney, spleen, distal pancreas, left adrenal and stomach, excision

- Paraganglioma/pheochromocytoma, tumor size 13.2 cm in greatest dimension. The tumor is centered in the upper pole of the kidney/left adrenal. Tumor invasion into renal parenchyma, adrenal parenchyma, pancreatic parenchyma and spleen parenchyma is identified. Tumor invades the muscularis of the stomach (from the deep aspect of the stomach, no mucosal gastric involvement is seen). Tumor invades into retroperitoneal adipose tissue.

- Necrosis and myxoid change are prominent in the central portions of the tumor (ie block F23)

- Tumor invades the skeletal muscle of the diaphragm

- The inked diaphragmatic margin overlying the tumor is involved with tumor (block F3). The gastric, ureter and pancreatic margin of this specimen is free of tumor, but please see specimens H and I which contain tumor at the pancreatic margins of additional tumor deposits.

TSS submitted dx discrepancy form stating the dx to be pheochromocytoma.

BCR

[page 2 of 6]
G: "Intrapancreatic neoplasm", excision
- Metastatic paraganglioma/pheochromocytoma, present within pancreatic parenchyma, with surrounding chronic pancreatitis

H: Pancreatic margin adjacent to intrapancreatic neoplasm, biopsy
- Pancreatic tissue with metastatic paraganglioma/pheochromocytoma

I: Pancreas, additional pancreatic margin, biopsy
- Pancreatic tissue with a microscopic (1 mm) focus of metastatic paraganglioma/pheochromocytoma

Comment:

The tumor in all of these specimens shows an endocrine appearing neoplasm composed of nests of tumor cells with granular, eosinophilic cytoplasm. This case has been previously biopsied and the tumor in this specimen is similar to the prior core biopsy tissue. That biopsy had a workup of immunohistochemical stains, and showed the tumor cells to be negative for immunostains for cytokeratin 7, 20, RCC, CD45 and inhibin, and positive for immunostains for synaptophysin, chromogranin, CD10 and S-100. The immunostain panel in conjunction with the morphology of the tumor is that of paraganglioma/pheochromocytoma. It is difficult to determine the exact site of origin of this tumor, as the tumor is so extensively infiltrative into the kidney, adrenal and pancreas, with invasion also present into the wall of the stomach and the spleen. The presence of metastatic disease supports the interpretation of malignant paraganglioma/pheochromocytoma. If this tumor is considered to be originating in the adrenal then it would be termed pheochromocytoma, and if it is thought to be of extra-adrenal origin then it would be termed paraganglioma, but biologically these are the same. Primary renal paragangliomas are extremely unusual but have been reported. The AJCC staging of this tumor is pT4, pN1. The primary tumor stage of pT4 is assigned to this case because of the multiple organ invasion, and is applicable regardless of which organ is designated as the primary site.

Intraoperative Consult Diagnosis:

A frozen section was requested by Dr. in

[page 3 of 6]
FSA1: Lymph node, celiac, biopsy
- Neoplasm, consistent with paraganglioma/pheochromocytoma

Drs. at .

Frozen Section Pathologist: , MD

Clinical History:

-year-old African American female with left retroperitoneal mass, concern for paraganglioma/pheochromocytoma.

Gross Description:

Received are nine appropriately labeled containers.

Container A is received fresh for frozen section and consists of a 0.6 x 0.5 x 0.3 cm red/tan soft tissue fragment which is frozen entirely as FSA1,

Container B is additionally labeled "retropancreatic lymph node." It holds a 0.9 x 0.7 x 0.4 cm lymph node candidate. This is bisected and submitted entirely in block B1,

Container C is additionally labeled "paraesophageal lymph node." It holds a 2.2 x 1.3 x 0.7 cm lymph node candidate. On sectioning, the cut surfaces reveal a pink/tan smooth surface. The specimen is submitted entirely in blocks C1-C2.

Container D is additionally labeled "celiac lymph node." It holds a 6.4 x 3.8 x 2.0 cm aggregate of tan/brown fibroadipose tissue. The specimen arrives with numerous plastic and metal surgical clips in place. The largest fragment on cut sectioning reveals a firm, white/tan ill-defined mass within the lymph node, concerning for malignancy. Representative sections are submitted in blocks D1 and D2. On sectioning the next largest fragment reveals a variegated red/brown/tan/white firm, multinodular cut surface. This is concerning for malignancy. Representative sections are submitted in blocks D3 and D4. The next fragment, which is serially sectioned, reveals a heterogeneous, largely red/brown parenchyma with central area of white, firm nodularity. Representative sections are submitted in blocks D5 and D6.

Container E is additionally labeled "left para-aortic lymph node." It holds a 6.7 x 3.5 x 3.0 cm mass of fibroadipose tissue. The specimen arrives with multiple plastic and metal

[page 4 of 6]
surgical clips in place. The mass is made up primarily of multiple matted lymph nodes making it difficult to accurately count the total number of lymph node candidates. There are at least six lymph node candidates identified. On sectioning, each of the lymph node candidates reveals a firm white/tan nodular with admixed red/brown parenchyma. Representative sections are submitted in blocks E1-E6.

Container F is additionally labeled "left retroperitoneal tumor with en bloc resection of left kidney, spleen, distal pancreas, left adrenal and portion of stomach." It holds a 16.0 x 14.0 x 14.0 cm specimen consisting of a 11.0 x 6.2 cm fragment of diaphragm, 15 x 8 x 6 cm spleen, 15.3 x 6.2 x 6.5 cm kidney, 6.1 x 2.8 x 1.5 cm pancreas, 3.4 x 1.1 x 0.5 cm adrenal gland, 3.1 x 2.7 cm open wedge of stomach. There is a 13.2 x 9.2 x 7.4 cm dominate mass which appears to arise from the upper pole of the kidney. The cut surface reveals a well circumscribed lobular soft tan/brown fleshy mass. There is focal hemorrhage along the superior edge of the mass. The mass markedly distorts the renal parenchyma, but appears confined within the kidney capsule. The corticomedullary junctions are distinct. The renal pelvis is compressed by the mass, but appears uninvolved. The 2 cm length of ureter is of normal caliber. The mass extends medially into the adrenal and abuts the gastric wall. The superior edge of the mass erodes through the diaphragm creating a 3.5 x 2 cm confluent area of nodularity. There is a 3.8 x 2.1 x 1.6 cm solid mass in the tail of the pancreas. The mass is solid white with a gritty cut surface and 2.5 cm from the green inked pancreatic body margin. The pancreatic tail mass is contiguous with a 6 x 5 x 3.5 cm splenic hilar mass with a firm, white, gritty cut surface. The mass has adherent fibrofatty tissue which is inked red. Sectioning through the spleen reveals direct extension of the pancreatic tumor into the spleen. The remaining splenic parenchyma is dark red and homogeneous. There are multiple white/tan fleshy nodules throughout the splenic parenchyma. The adrenal gland appears to directly overlies the fleshy mass, the cortex becomes markedly thin (F6).

Block summary:

(Inking: diaphragm=blue, pancreatic margin=green, adrenal=orange, stomach margin=black)

- F1 - ureter and vascular margins
- F2 - pancreatic body margin, en face
- F3 - tumor and overlying diaphragm, blue ink
- F4 - closest diaphragm margin, en face (posterior)

[page 5 of 6]
F5 - en face gastric staple margin
F6-F8 - adrenal gland and tumor
F9 - tumor and renal capsule, superior
F10 - tumor and kidney
F11 - tumor and renal sinus
F12 - tumor and kidney
F13 - mass with adrenal and pancreas
F14, F15 - spleen and mass
F16 - junction of pancreatic mass and fleshy kidney mass
F17 - splenic hilar mass
F18 - pancreatic mass
F19 - tumor and gastric wall
F20-F25 - representative sections of fleshy mass in kidney

Container G is additionally labeled "intrapancreatic neoplasm." It holds a 1.9 x 1.1 x 0.8 cm tan/yellow rubbery nodule. On sectioning, the cut surface reveals an ill-defined yellow/tan firm mass. The specimen is submitted entirely in blocks G1 and G2.

Container H is additionally labeled "pancreatic margin adjacent to intrapancreatic neoplasm." It holds a 1.6 x 1.2 x 0.6 cm red/tan soft tissue fragment with a surgical clip in place. The surgical clip is removed and the specimen is bisected and submitted entirely in block H1.

Container I is additionally labeled "additional pancreatic margin." It holds a 2.7 x 1.2 x 1.1 cm fragment of red/tan firm tissue. There is a 1.0 cm staple line which is removed and the underlying parenchyma is inked black. The specimen is serially sectioned and the cut surfaces reveal tan/brown surface with lobulated pattern. The specimen is submitted entirely in blocks I1 and I2.

[page 6 of 6]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	based on the statement, "appears to arise from the upper pole of the kidney" found in the path report, however, this case involved the entire retroperitoneal space and is impossible to separate the origin.	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	tissue banked and submitted is from adrenal gland which is consistent with pheochromocytoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	pathologists and surgeon were unable to determine the exact originating site as the tumor was large and "involved the entirety of the left retroperitoneum". An en bloc resection of left kidney, spleen, distal pancreas, left adrenal and stomach was performed. If it arises from the adrenal would be called pheochromocytoma. If is extra-adrenal origin, would be designated paraganglioma. Biologically they are the same. Site of origin could not be determined.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	at time of submission to TCGA, reviewed the case.	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Date

Source: NCI Genomic Data Commons file fc70f1ec-4ea0-4a2c-8458-4417a3fb99a7 (TCGA-QT-A5XJ.C345B53B-7C88-48DA-9BE1-E9BDB2A6D474.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).